Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8K7, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8K7-01B (Primary Tumor).

[page 1 of 4]
printed

UUID: 29FC671C-98D1-4A34-8FC7-5C667E5FD836 TCGA-VD-ABK7-01A-PR		Page 1 of 4
Redacted REPORT Tel: [Redacted]  		Clinical Consultant & Location [Redacted] [Redacted]
Unit No [Redacted]	Sex [Redacted]	

This Copy For:

SPECIMEN

Left globe

CLINICAL DETAILS

Left choroidal melanoma and rubeotic glaucoma and total retinal detachment.

MACROSCOPIC DESCRIPTION

An intact left eye.

Dimensions: Axial 25mm, Horizontal 25mm, Vertical 24mm

Cornea: Horizontal 12mm, Vertical 11mm
Description: clear

Optic nerve
Length 6mm, Diameter 4mm

Anterior chamber: normal depth

On trans-illumination, a shadow is seen measuring 18 x 16mm located laterally.

Plane of section: horizontal

Intraocular description: On opening, a large mushroom-shaped non-pigmented choroidal melanoma is seen, with an area of necrosis. Total funnel-shaped retinal detachment.

Tumour size: LBD 17mm, Height 13mm

MICROSCOPY

Histological sections demonstrate an enucleated eye with a regular cornea, a narrow anterior chamber and closed angles as a result of rubeosis iridis. the ciliary muscles are moderately atrophic and there is hyalinisation of the ciliary processes. The lens shows moderate cataractous changes.

In the posterior segment, a large choroidal melanoma can be

*2100-3
Melanoma, spindle cell NGS 8772/3*

*Date: 10 Choroid 069.3
9/11/14*

Reported:

Pathologist:

Electronically Verified:

[page 2 of 4]
Department of Pathology

Page 2 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]		Clinical Consultant & Location [REDACTED] [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED] [REDACTED]	Request Date [REDACTED]		

This Copy For:

seen. This is dome-shaped with a total retinal detachment with extensive subretinal fluid. The retina demonstrates advanced atrophy with degenerative changes.

The tumour is not pigmented and consists predominantly of spindle cells, with numerous balloon cells. The melanoma cells are immunoreactive for MelanA and HSP-27 (score 2).

The number of mitoses is approx. 4/40 high power fields.

The microvasculature of the melanoma is prominent, and closed loops are present in the tissue planes evaluated. Occasional "vascular lakes" can be observed, and in these tumour cells can be seen located within the lumen.

The lymphocytic infiltrate within tumour is minimal. Macrophages are scattered throughout the tumour in a mild density.

There is no evidence of scleral invasion or of extraocular growth. The optic nerve is tumour free, and demonstrates mild atrophic changes. The examined vortex veins are free of tumour.

DIAGNOSIS

Enucleated eye - choroidal melanoma of spindle cell type.

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	2= Spindle B
CT LOOPS	2= Closed loops
NECROSIS	No
PIGMENTATION	No

Reported:

Pathologist:

Electronically Verified:

[page 3 of 4]
Department of Pathology

Page 3 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]	

This Copy For:

LYMPHOCYTIC INFILTRATION Yes
MITOTIC FREQUENCY 4/40 HPF
DIFFUSE MELANOMA No

SPREAD 1 = None

CLEARANCE 2= Adequate

HSP-27 POSITIVITY 2= 21-70%

LARGE DIAMETER 17 mm
THICKNESS 13 mm

COMMENTS:

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8.

A supplementary report will follow as soon as these investigations are complete.

SUPPLEMENTARY REPORT

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED] which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is

Reported:

Pathologist:

Electronically Verified:

[page 4 of 4]
Department of Pathology

Page 4 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

printed on a separate report.

In summary, sequence analysis demonstrated normal chromosomes 1, 3 and 8, as well as a gain in chromosome 6p.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist:

Electronically Verified:

Source: NCI Genomic Data Commons file 37c8f3c4-c43b-4133-b70a-201e16f9f086 (TCGA-VD-A8K7.29FC671C-98D1-4A34-8FC7-5C667E5FDB36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).